Surgical pathology report (de-identified scan), TCGA case TCGA-ND-A4W6, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Cedars Sinai, specimen TCGA-ND-A4W6-01A (Primary Tumor).

[page 1 of 4]
Patient:

Hospital No:
Date of Birth:
Age/Sex: F

Location:

Pathologist:
Assistant:
Date of Procedure:
Date Received:

Accession Number:

Ordering M.D.:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS: Malignant mixed mullerian tumor of the uterus, fallopian tubes, and ovaries.

A. LEFT TUBE AND OVARY:

- Ovary and fallopian tube with multiple foci of papillary carcinoma, predominantly in the lumen of vessels

B. RIGHT TUBE AND OVARY:

- Ovary and fallopian tube with multiple foci of papillary carcinoma, predominantly in the lumen of vessels

C. UTERUS AND CERVIX:

- Malignant mixed mullerian tumor of the endometrium infiltrating the entire thickness of the myometrium with extensive vascular invasion
- Cervix: Foci of papillary serous carcinoma within vessels
- Leiomyoma with foci of papillary serous carcinoma within vessels

D. RIGHT PARAAORTIC LYMPH NODE:

- Metastatic papillary serous carcinoma in lymph node extending to perinodal connective tissue

E. OMENTUM BIOPSY:

- Adipose tissue, no tumor present

COMMENT: This malignant mixed mullerian tumor is composed of papillary serous carcinoma, approximately 50%, and sarcoma, with extensive areas of rhabdomyosarcoma, approximately 50%. All the foci of tumor in the myometrium, cervix, fallopian tubes and ovaries consist of only papillary serous carcinoma.

SYNOPTIC REPORT:

Applies To:

A : LEFT TUBE AND OVARY
B : RIGHT TUBE AND OVARY
C : UTERUS AND CERVIX
D : RIGHT PERIAORTIC LYMPH NODE
E : OMENTUM BIOPSY

ICD-3
Carcinosarcoma / Mixed Mullerian
Tumor, malignant 8950/3
Site: Corpus Uteri, endometrium
C 54.1
JDS 3/18/13

Microscopic

Histologic Type: Malignant mixed mullerian tumor

Tumor Size: Dimensions: 12 x 10 x 8cm

Myometrial Invasion: Greater than 50% myometrial invasion

Patient Case(s):

Copy For

Page 1 of 4

PATIENT NOTIFIED OF RESULTS		
DR:	NURSE:	DATE:

[page 2 of 4]
PATIENT:

ACCESSION #:

Involvement of Cervix: Invasion of cervical stromal connective tissue

Margins: Uninvolved by invasive carcinoma

Lymphovascular Invasion: Present

Pathologic Staging (pTNM) AJCC 7th Edition 2010

Primary Tumor (pT): pT3a : Tumor involves serosa and/or adnexa (direct extension or metastasis)

Regional Lymph Nodes (pN): pNX: Cannot be assessed

Number of para-aortic lymph nodes examined: 1

Number of para-aortic lymph nodes involved: 1

HISTORY: Vaginal discharge

MICROSCOPIC FINDINGS: See diagnosis.

GROSS:
A. LEFT TUBE AND OVARY

Labeled , designated "left tube and ovary", and received in formalin is an intact adnexa consisting of a short segment of non-fimbriated fallopian tube measuring 2.6 cm long and 1.2 cm in diameter intimately attached to a 2.6 x 2.5 x 1.6 cm ovary. The fallopian tube lumen ranges from pinpoint to 0.4 cm in diameter. The cut surface of the ovary is ill-defined mottled and pink-tan to white. The overlying capsular surface is disrupted and shaggy. There is attached blood clot and fibrous adhesions on the mesosalpinx of the fallopian tube.

Ink key: black - external surface of adnexa.

Representative sections are submitted.

Slide key:

A1-A3. Fallopian tube with attached ovary - 1 each

B. RIGHT TUBE AND OVARY

Labeled , designated "right tube and ovary", and received in formalin is an intact adnexa consisting of a non-fimbriated segment of fallopian tube measuring 6.4 cm long and average diameter of 1.5 cm attached to a 2.5 x 2.0 x 1.4 cm ovary. The attached mesosalpinx and fibrovascular paraovarian tissue measures 4.5 x 2.5 x 1.0 cm. The ovary has a mottled pink-tan to white cut surface. The capsule is shaggy and granular. The ovary has a patent lumen ranging from pinpoint to 0.2 cm in diameter. The mesosalpinx has a shaggy surface with attached adhesions. The paraovarian soft tissue is thickened and edematous.

Ink key: black - external surface of adnexa.

Representative sections are submitted.

Slide key:

B1. Fallopian tube cross sections - 2

B2, B3. Bisected presumed non-fimbriated distal end of fallopian tube - 2

B4. Ovary - 2

B5. Paraovarian tissue - 2

[page 3 of 4]
PATIENT:

ACCESSION #:

C. UTERUS AND CERVIX FS

Labeled _____, designated "uterus and cervix FS", and received fresh for intraoperative consultation is a 1331.5 gram total hysterectomy specimen. It measures 13.4 cm ectocervix to fundus, 14.0 cm cornu to cornu, and approximately 14.0 cm anterior to posterior. The cervical portion of the uterus is 3.0 cm long and up to 6.7 cm in maximum diameter. The endometrial cavity is approximately 12.0 cm long and 10.0 cm wide. The myometrial thickness ranges from 1.4 to 3.5 cm.

There is a large fungating mass entirely filling the endometrial cavity (12.0 x 10.0 x 8.0 cm). It is primarily based in the uterus with extension into both the anterior and posterior lower uterine segments. The mass is located 4.2 cm from the anterior ectocervix and 1.6 cm from the posterior ectocervix. On the adjacent myometrium are several separate polypoid masses ranging from 1.0 to 2.2 cm in greatest dimension. The small portions of intervening myometrium range from smooth to pink-tan with an average thickness of 0.3 cm to bulky solid and tan-white with a thickness of 0.6 cm. The exophytic portions of the mass range from soft glistening to pink-tan to firm tan-white and whorled. The surface of the exophytic mass is gray-yellow and necrotic appearing. Approximately 20% to 30% of the mass is necrotic appearing. The entire mass is superficial with focal probable invasion. In the fundus of the anterior side there is invasive to 0.4 cm out of a total myometrial thickness of 1.5 cm (less than 50%). In the remaining uterus the mass is not grossly invasive. Separately received is an aggregate of polypoid necrotic and hemorrhagic mass measuring 11.0 x 7.0 x 5.0 cm in aggregate.

Within the myometrium are approximately 20 to 30 subserosal and intramural nodules ranging from 0.6 to 5.8 cm in diameter. All of the nodules have a firm tan-white whorled cut surface. Areas of hemorrhage necrosis are not identified. In one of the middle-sized subserosal nodules are focal calcifications. The intervening myometrium is pink-tan and rubbery. On the serosal aspect of the uterine corpus are several small fibrous adhesions. The endocervical canal is dilated with a flat tan-brown faintly granular mucosal surface.

Ink key:

Blue - anterior paracervical tissue and uterine corpus serosa
Black - posterior paracervical soft tissue and uterine corpus serosa
Orange - inferior portion of lower uterine segment sections

A representative section is submitted for frozen section, and further submitted for permanent sections. Representative sections are submitted. Gross photographs are taken.

Slide key:

C1. Anterior cervix - 1
C2. Anterior lower uterine segment with mass - 1
C3-C5. Trisected mass anterior side mid corpus - 1 each
C6, C7. Bisected full thickness section of anterior fundus with soft glistening portion of mass and probable deepest mass invasion - 1 each
C8-C10. Additional full thickness trisected anterior fundus with soft glistening portion of mass - 1 each
C11, C12. Representative sections of separately received tumor - 1 each
C13. Posterior cervix - 1
C14. Posterior lower uterine segment - 1
C15, C16. Bisected mid portion of posterior uterine corpus with mass - 1 each
C17-C19. Posterior fundus trisected full thickness section with solid firm whorled component of mass - 1 each
C20. Representative posterior leiomyomata - 4
C21. Representative anterior leiomyomata - 4
C22. Frozen section remnant - 1

D. RIGHT PARAAORTIC LYMPH NODE

[page 4 of 4]
PATIENT:

ACCESSION #:

Labeled _____, designated "right paraaortic lymph node", and received in formalin is a 3.0 x 1.4 x 0.9 cm semifirm candidate lymph node. The cut surface is partially cystic with a solid tan-white tumor deposit measuring 1.3 cm in greatest dimension. The candidate node is representatively submitted.
D1. 4

E. OMENTAL BIOPSY

Labeled _____, designated "omental biopsy", and received in formalin is a portion of finely lobulated tan-yellow fibroadipose tissue consistent with omentum measuring 7.0 x 4.0 x 0.6 cm. Mass lesions are not identified. Representative sections are submitted.

E1. Multiple

Gross dictated by

INTRAOPERATIVE CONSULTATION: _____
OPERATIVE CALL
OPERATIVE CONSULT (FROZEN):

FSC. UTERUS AND CERVIX:

- Uterine cavity filled by polypoid mass of tumor
- grossly superficially invasive high-grade malignant tumor

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
Electronically signed

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file b9d0c232-8691-4c1c-b4af-f7e51f18194e (TCGA-ND-A4W6.F3CE442E-9166-401C-9E54-4852EC7285F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).